Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64R, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64R-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A.- C. Brain, right frontal mass #1, #2, #3, resection and : Low grade oligodendroglioma with focal increased cellularity and mild increase in mitotic activity (WHO grade II).

Immunohistochemical stains were performed on paraffin embedded tissue using antibodies to IDH1 (R132H), p53, and Ki-67. IDH1(R132H) immunostain is positive consistent with IDH1 mutation. p53 protein is expressed in rare cells. Ki-67 labeling varies from low to focally moderate. These findings support the above diagnosis.

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the . For interpretation, see

Interpreted by:

Report electronically signed by

Transcribed by:

Preliminary Frozen Section Consultation:

A. Brain, right frontal mass #1, smears: Glioma, favor oligodendroglioma. Hold over to confirm on permanent sections and to grade.

continued next page Page 1 of 2

ICD-O-3
Oligodendroglioma NOS
with 9450/3
Site (R) Brain, frontal lobe
C64F Brain, supratentorial NOS
C71.0

[page 2 of 2]
Intraoperative cytologic smear(s) interpretation performed b

Gross Description:

- A. Received fresh labeled "right frontal mass" is a 5.6 x 4.8 x 2.1 cm portion of brain with a 2.6 x 1.2 x 1.2 cm tan-gray ill-defined lesion. Smears prepared. Representative sections are submitted. Grossed by
- B. Received fresh labeled "right frontal mass #2 - brain" is a 1.7 x 1.0 x 0.8 cm portion of brain. All submitted for permanent sections only. Grossed by
- C. Received fresh within a trap labeled ' collection sock - brain" is a 5.0 x 4.0 x 2.0 cm aggregate of gray-white tissue. All submitted for permanent sections only. Grossed by

Block Summary:

Part A: Right frontal mass brain

- 1 Rt frontal brain mass 1
- 2 Rt frontal brain mass 2
- 3 Rt frontal brain mass 3
- 4 Rt frontal brain mass 4
- 5 Rt frontal brain mass 5
- 6 Rt frontal brain mass 6
- 7 Rt frontal brain mass 7

Part B: Right frontal mass #2-brain

- 1 Rt frontal brain mass #2-1
- 2 Rt frontal brain mass #2-2

Part C: collection sock-brain

- 1 Brain collection 1
- 2 Brain collection 2
- 3 Brain collection 3
- 4 Brain collection 4
- 5 Brain collection 5
- 6 Brain collection 6
- 7 Brain collection 7
- 8 Brain collection 8
- 9 Brain collection 9
- 10 Brain collection 10
- 11 Brain collection 11

END OF REPORT

Page 2 of 2

Criteria	4/2/13	Yes	No

Source: NCI Genomic Data Commons file a755947b-f43e-482d-8db2-cf44ac0c675f (TCGA-DB-A64R.A9F5EDE4-1FC5-4E6D-BEA1-70B6223A49FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).